Somatic mutation profile of tumor specimen ALCH-B421-TTP1-A (aliquot ALCH-B421-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B421, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.3 years (23,125 days).
Specimen ALCH-B421-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cffbaa5b-c094-44bb-baf3-bd8d691a3960.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B421-NB1-A (Blood Derived Normal), aliquot ALCH-B421-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5440c72c-b94e-458f-a44d-24a7b9524404

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- CLK1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1172865050; called by muse, mutect2
- EXD3 | c.832-1G>C p.X278_splice | Splice Site (SNP) | VAF 15/186 reads (8%) | catalogued as COSV100573690; called by muse, mutect2
- GTF3C3 | c.2491A>G p.I831V | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.043); catalogued as rs1382096480, COSV99826832; called by muse, mutect2
- L1CAM | c.1774G>A p.V592M | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as rs181210798; called by muse, mutect2, varscan2
- ROR2 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 16/170 reads (9%) | catalogued as rs1012552188; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1976C>T p.T659M (on ENST00000540229 / NM_001371097.1; = p.T598M on NM_001009562.4) | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs753900713, COSV67449849; called by muse, mutect2
- SPAG16 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV99793831; called by muse, mutect2
- TOPAZ1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.231); catalogued as rs1388551937, COSV59067202; called by muse, varscan2
- ZNF608 | c.2583T>G p.N861K | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as COSV60440811; called by muse, mutect2
- ZNF8 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs961843396; called by muse, mutect2, varscan2
- DSP | c.8413G>T p.A2805S | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- F13A1 | c.799-1G>A p.X267_splice | Splice Site (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- NCBP1 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PCLO | c.7874C>G p.P2625R | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2
- PODXL2 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SUGP2 | c.1675A>T p.I559F | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2
- ZNF112 | c.812C>G p.S271C (on ENST00000337401 / NM_001083335.2; = p.S265C on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- APBA2 | c.606C>T p.N202= | Silent (SNP) | VAF 17/333 reads (5%) | catalogued as rs761618105; called by muse, mutect2
- GRIN2A | c.4230G>T p.S1410= | Silent (SNP) | VAF 49/631 reads (8%) | catalogued as COSV58041112; called by muse, mutect2
- MSLNL | c.1962C>G p.L654= | Silent (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- RYR3 | c.13359C>T p.D4453= (on ENST00000389232; = p.D4454= on NM_001036.6) | Silent (SNP) | VAF 22/333 reads (7%) | catalogued as rs748783723, COSV66787434; called by muse, mutect2
- SAP130 | c.657T>G p.P219= | Silent (SNP) | VAF 18/402 reads (4%) | called by muse, mutect2
- SMPD3 | c.807C>T p.N269= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs892110854, COSV54710136; called by muse, mutect2, varscan2
- ZMYM4 | c.993A>G p.S331= | Silent (SNP) | VAF 25/333 reads (8%) | catalogued as rs1176932993; called by muse, mutect2
